CCDI case PBBIRI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/45b1ea41-6f34-4e66-bc40-b4f33f153629

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,395 days).

Biospecimens (3 samples)
- Sample 0D9DQT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9DQU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D9DQW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
